Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A7CF, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A7CF-01A (Primary Tumor).

Episode No:		
Lab No:		
Specimen: Tissue	D.O.B:	Sex: F
Collected:	Location:	

CLINICAL:

Grade II insular glioma.

MACROSCOPIC:

A. Specimen labelled "1 brain tumour", consists of multiple pieces of light grey to tan glial tissue ranging in size between 3-16mm, with an aggregate measurement of 40 x 25 x 6mm. AE 2 blocks.

B. Specimen labelled "2 most aggressive tumour", consists of a 2 x1x1mm fragment of tan tissue. AE 1 block.

MICROSCOPIC:

A, B. All tissue pieces are extensively infiltrated by a glioma. The cellularity varies from moderate in the sample labelled "1 brain tumour", to more cellular in the 2nd specimen labelled "2 most aggressive tumour". Moderate cellular pleomorphism is noted, which is perhaps more prominent in specimen 1. Only very rare mitotic figures are identified in the "1 brain tumour" and there are no mitotic figures in "2 most aggressive tumour". There is no necrosis or perivascular proliferation.

Immunoperoxidase stains:

Ki-67 (proliferative index): is well under 1% in both specimens.

Despite the finding of very rare mitotic figures, the overall features are considered to be within the spectrum of a diffuse astrocytoma (WHO grade 2).

SUMMARY:

A, B. Brain tumour, biopsies:

DIFFUSE ASTROCYTOMA (WHO grade 2).

ICD-O-3

Astrocytoma, grade III 9400/3
Site: Brain, Supratentorial NOS C71.0

By Brain, insular C71.0
9/25/13

Primary.
Recurrent submission to follow.
Recurrent astrocytoma III

II/III/IV Discrepancy		✓

Distribution: FILE-COPY,

Source: NCI Genomic Data Commons file cedc80ce-d34c-4f9e-8159-8435a654fffa (TCGA-TM-A7CF.CC5699A6-8FC6-438D-ACC4-907481E6A580.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).